Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3864, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3864-01A (Primary Tumor).

Diagnosis

Right hemicolectomy preparation with a cecal carcinoma histologically characterized as a moderately differentiated colorectal adenocarcinoma, almost completely covering the cecum, and measuring 5.5cm in diameter at the widest point. Invasive spreading of the tumor within all intestinal walls up to the bordering fatty tissue and the subserosa.

Oral and aboral resection margins are tumor-free as is the greater omentum.

21 mesocolic and mesenteric lymph nodes are tumor-free with uncharacteristically reactive lesions.

Therefore the tumor stage is: pT3, pN0 (0/21) L0, V0; G2

Source: NCI Genomic Data Commons file b3ba2f4b-324e-4b11-bd97-91573faeabbb (TCGA-AA-3864.B44B2737-EA1F-4280-A3DE-4E5FA43B8E93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).